Somatic mutation profile of tumor specimen C3L-00586-03 (aliquot CPT0023630006) from CPTAC case C3L-00586, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 50.9 years (18,580 days).
Specimen C3L-00586-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ea64f4c-e16a-4dd7-9892-8bbff596c46d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00586-31 (Blood Derived Normal), aliquot CPT0024590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a68db551-9b3e-4d2b-a80d-19ea003ed54f

The open-access MAF lists 13,533 somatic variants for this specimen: 9,494 protein-altering or splice-affecting, 2,466 silent, 1,573 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,254, Silent 2,466, Nonsense Mutation 901, Intron 769, 3'UTR 257, RNA 247, Splice Site 189, 5'UTR 130, Splice Region 110, 5'Flank 93, 3'Flank 76, Frame Shift Ins 19.

Variants (750 of 13,533; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.330+1G>A p.X110_splice | Splice Site (SNP) | VAF 19/373 reads (5%) | catalogued as rs375415632, CS043116; ClinVar: likely pathogenic; called by muse, mutect2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 41/141 reads (29%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASNS | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 94/278 reads (34%) | catalogued as rs373645939; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASS1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 98/554 reads (18%) | catalogued as rs786204537, CM091427; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- BEST1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs28940278, CM001378, COSV57122378; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs80358438, CM110364, COSV66448948, COSV66461911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 31/199 reads (16%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as rs1557110988; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.*599C>T | 3'UTR (SNP) | VAF 29/245 reads (12%) | catalogued as rs755097302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC2LI1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 9/97 reads (9%) | catalogued as rs745930390, CM157152, COSV53182974; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 56/220 reads (25%) | catalogued as rs724159953, CM1510739, COSV58292386; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDA | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs132630312, CM980583, COSV65772037; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EP300 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 42/260 reads (16%) | catalogued as rs137853039, CM052869, COSV54332975; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPG5 | c.2575G>T p.E859* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs587776941, CM1212059, COSV56346108; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 94/279 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV57250290, COSV57259763, COSV57263441; called by muse, mutect2, varscan2
- F8 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 42/264 reads (16%) | catalogued as rs137852368, CM880025; ClinVar: pathogenic; called by muse, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 87/259 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 15/196 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2
- FOXN1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 66/555 reads (12%) | catalogued as rs104894562, CM991251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GPC3 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 56/282 reads (20%) | catalogued as rs1569392947; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HBB | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 100/551 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs34165323, CM942327; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HUWE1 | c.12559C>T p.R4187C | Missense Mutation (SNP) | VAF 116/452 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121918527, CM081661, COSV99470874; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IRF6 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 150/400 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769068305, CM092364, COSV99671125; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 60/299 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KMT2C | c.10213C>T p.R3405* | Nonsense Mutation (SNP) | VAF 44/256 reads (17%) | catalogued as rs1485613651, COSV51420934; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 77/244 reads (32%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 43/176 reads (24%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 123/231 reads (53%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCSK9 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs793888521, CM164687; ClinVar: likely pathogenic; called by muse, mutect2
- PIEZO2 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as rs1568069621, COSV57430364; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55876538, COSV55894288; called by muse, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 86/308 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- POLG | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs121918046, CM030939, COSV51520019; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 143/477 reads (30%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.528T>G p.Y176* | Nonsense Mutation (SNP) | VAF 52/232 reads (22%) | catalogued as rs1057522285, CM020756, CM033668, CX135246, COSV64292861; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPS6KA3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs122454127, CM992428, COSV65387529; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- SCN1A | c.5674C>T p.R1892* (on ENST00000303395 / NM_001202435.3; = p.R1881* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/328 reads (7%) | catalogued as rs794726739, CM024313, CM162662, COSV100318718; ClinVar: pathogenic; called by muse, mutect2
- SMAD4 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 26/188 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV61687696; called by muse, mutect2, varscan2
- SPAST | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1553317025, CM022250; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SPINK5 | c.2557C>T p.R853* | Nonsense Mutation (SNP) | VAF 127/450 reads (28%) | catalogued as rs753621591, CM121226, COSV56252267; ClinVar: pathogenic; called by muse, varscan2
- SPRED1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518150, COSV54438109, COSV54438678; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SRD5A3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772795484, COSV51711296; ClinVar: likely pathogenic; called by mutect2, varscan2
- TMEM67 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 33/118 reads (28%) | catalogued as rs751517725, COSV60036110; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNFRSF11A | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs121908658, CM083187; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 97/433 reads (22%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.40399C>T p.R13467* (on ENST00000591111; = p.R6043* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 124/361 reads (34%) | catalogued as rs1060500405, COSV59862588; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV100228952; called by muse, mutect2, varscan2
- AAK1 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104432574; called by muse, mutect2, varscan2
- AASDH | c.2728C>A p.H910N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV99221186; called by muse, mutect2, varscan2
- ABCA1 | c.721-1G>T p.X241_splice | Splice Site (SNP) | VAF 41/294 reads (14%) | catalogued as COSV101036821, COSV66066833; called by muse, varscan2
- ABCA10 | c.3163-1G>T p.X1055_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as COSV52220894; called by muse, mutect2, varscan2
- ABCA12 | c.2851G>A p.E951K (on ENST00000272895 / NM_173076.3; = p.E633K on NM_015657.3) | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1353723813, COSV55948964; called by muse, varscan2
- ABCA12 | c.1396G>A p.E466K (on ENST00000272895 / NM_173076.3; = p.E148K on NM_015657.3) | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.033); catalogued as rs776834147; called by muse, mutect2, varscan2
- ABCA13 | c.2668G>T p.D890Y | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1334169510; called by muse, mutect2, varscan2
- ABCA13 | c.4759G>T p.E1587* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV70026130, COSV70027603; called by muse, mutect2, varscan2
- ABCA13 | c.6880G>T p.D2294Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV70034370; called by muse, mutect2, varscan2
- ABCB1 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); catalogued as COSV55944621, COSV55950626; called by muse, mutect2
- ABCB5 | c.2812C>T p.R938* (on ENST00000404938 / NM_001163941.2; = p.R493* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 20/150 reads (13%) | catalogued as rs199675268, COSV51706976; called by muse, mutect2, varscan2
- ABCB7 | c.340G>T p.D114Y (on ENST00000373394 / NM_001271696.3; = p.D115Y on NM_004299.6) | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV53718464; called by muse, mutect2
- ABCB9 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287075211, COSV54894413; called by muse, mutect2, varscan2
- ABCC11 | c.4111G>A p.A1371T | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs139034695, COSV62324823; called by mutect2, varscan2
- ABCC11 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.442); catalogued as COSV62325224; called by muse, mutect2
- ABCC12 | c.3964G>T p.D1322Y | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60914657; called by muse, mutect2, varscan2
- ABCC12 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs774878802; called by mutect2, varscan2
- ABCC2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 83/523 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs537368151; called by muse, mutect2, varscan2
- ABCC8 | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs764495675; called by muse, mutect2
- ABCC9 | c.1367C>A p.A456E | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99684716; called by muse, mutect2
- ABCC9 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV53961740, COSV99686289; called by muse, varscan2
- ABCC9 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53967489; called by muse, mutect2, varscan2
- ABCD1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 26/481 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs782598285; called by muse, mutect2
- ABCD2 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1405641865, COSV104394064; called by muse, mutect2, varscan2
- ABCG1 | c.1960G>A p.V654I | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as rs373692935; called by muse, mutect2, varscan2
- ABHD12 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 63/337 reads (19%) | catalogued as rs773146728; called by muse, mutect2, varscan2
- ABHD6 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV99917084; called by muse, mutect2, varscan2
- ABHD8 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53112525; called by muse, mutect2, varscan2
- ABR | c.307G>A p.E103K (on ENST00000302538 / NM_021962.5; = p.E66K on NM_001092.5) | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765419742, COSV99347590; called by muse, mutect2, varscan2
- ABRA | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 38/216 reads (18%) | catalogued as rs200867691; called by muse, mutect2, varscan2
- ABTB2 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1173284303, COSV54387774; called by muse, mutect2, varscan2
- AC004593.2 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs753390011, COSV56087648; called by muse, mutect2
- AC006059.2 | c.2017G>A p.D673N | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs760500767, COSV100045456, COSV59608239; called by muse, mutect2, varscan2
- AC006059.2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 114/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182436192, COSV59606181; called by muse, mutect2, varscan2
- AC008397.2 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99442455; called by muse, mutect2, varscan2
- AC008676.3 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs1351443971; called by muse, mutect2, varscan2
- AC023055.1 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs775763541, COSV60242850; called by muse, mutect2, varscan2
- AC068633.1 | n.141C>T | Splice Region (SNP) | VAF 17/171 reads (10%) | catalogued as rs1033295889; called by muse, mutect2, varscan2
- AC099489.1 | c.3463G>A p.G1155S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as rs1371387540; called by muse, mutect2, varscan2
- AC244197.3 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as CM940965; called by muse, varscan2
- ACACA | c.3349C>T p.R1117* | Nonsense Mutation (SNP) | VAF 107/384 reads (28%) | catalogued as rs1439805556; called by muse, mutect2, varscan2
- ACACB | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | catalogued as COSV58128517; called by muse, varscan2
- ACACB | c.3715C>T p.R1239W | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs367785362; called by muse, mutect2, varscan2
- ACACB | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs143327495, COSV100622465; called by muse, mutect2
- ACAD11 | c.2281C>A p.L761I | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53896401; called by muse, varscan2
- ACADVL | c.1459C>A p.L487I | Missense Mutation (SNP) | VAF 24/576 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV99138438; called by muse, mutect2
- ACAP2 | c.1611G>T p.K537N | Missense Mutation (SNP) | VAF 31/355 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV58753270; called by muse, mutect2
- ACCSL | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1432343767, COSV66580499; called by muse, mutect2, varscan2
- ACE2 | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53023844; called by muse, mutect2, varscan2
- ACO1 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV59385325; called by muse, mutect2
- ACOD1 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 14/198 reads (7%) | catalogued as rs1282475125; called by muse, mutect2
- ACOD1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1343813316; called by muse, mutect2, varscan2
- ACRBP | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168368064; called by muse, varscan2
- ACSBG1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs761047347, COSV99357019; called by muse, mutect2
- ACSBG2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs868360772; called by muse, mutect2, varscan2
- ACSL4 | c.358C>A p.L120I (on ENST00000340800 / NM_022977.2; = p.L79I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV61614846; called by muse, mutect2, varscan2
- ACSM1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs200490565; called by muse, mutect2
- ACSM2B | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV61656991; called by muse, mutect2
- ACSM2B | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 91/270 reads (34%) | catalogued as COSV61657257; called by muse, varscan2
- ACSM2B | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs776526040; called by mutect2, varscan2
- ACSM4 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1412358684, COSV68067591, COSV68067628; called by muse, mutect2, varscan2
- ACTN1 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs1245722350; called by muse, mutect2, varscan2
- ACTN2 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 127/429 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs1060503686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR3 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54298976; called by muse, varscan2
- ACTRT1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.073); catalogued as rs1489609921; called by muse, varscan2
- ACTRT1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs192777796; called by muse, varscan2
- ACTRT1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866190279, COSV64419414, COSV64420169; called by muse, mutect2, varscan2
- ACVR1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1034717563; called by muse, mutect2, varscan2
- ACVR2B | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 68/362 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as rs371445433; called by muse, mutect2, varscan2
- ACVRL1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66360620; called by muse, mutect2
- ADAM10 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99546123; called by muse, mutect2
- ADAM18 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1246777253, COSV55846487; called by muse, mutect2, varscan2
- ADAM22 | c.992+1G>A p.X331_splice | Splice Site (SNP) | VAF 36/171 reads (21%) | catalogued as rs777318270, COSV55973293; called by muse, mutect2, varscan2
- ADAM28 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.762); catalogued as rs1392638105, COSV56099330, COSV56100596; called by muse, mutect2, varscan2
- ADAM29 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63662004; called by muse, mutect2
- ADAM30 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as COSV65561767; called by muse, mutect2, varscan2
- ADAM32 | c.1294T>A p.C432S | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65952803; called by muse, mutect2, varscan2
- ADAMDEC1 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as rs1454716974, COSV56474828; called by muse, mutect2, varscan2
- ADAMDEC1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.213); catalogued as rs932488074; called by muse, mutect2, varscan2
- ADAMTS16 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs377507889; called by muse, mutect2, varscan2
- ADAMTS17 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs765090779, COSV51472944; called by muse, mutect2
- ADAMTS18 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 156/535 reads (29%) | catalogued as rs747773771, COSV51398816; called by muse, mutect2, varscan2
- ADAMTS19 | c.814A>C p.T272P | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV50731352; called by muse, mutect2
- ADAMTS19 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 28/146 reads (19%) | catalogued as rs772148624, COSV50749719, COSV50758055; called by muse, varscan2
- ADAMTS2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99201001; called by muse, varscan2
- ADAMTS20 | c.4730C>A p.S1577Y | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV67133107; called by muse, mutect2
- ADAMTS3 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.629); catalogued as rs777999211; called by muse, mutect2, varscan2
- ADAMTS3 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54398247; called by muse, varscan2
- ADAMTS8 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1011505384; called by muse, mutect2
- ADAMTS9 | c.3569C>A p.S1190Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs781275665, COSV55788989; called by mutect2, varscan2
- ADAMTSL1 | c.2510T>C p.F837S | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.05); catalogued as rs180981384; called by muse, mutect2, varscan2
- ADAP2 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292639951, COSV58296004; called by muse, mutect2
- ADARB2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1322029552, COSV67228331; called by muse, mutect2
- ADCY1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52033824; called by muse, mutect2
- ADCY1 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032751; called by mutect2, varscan2
- ADCY10 | c.2743G>T p.E915* | Nonsense Mutation (SNP) | VAF 121/335 reads (36%) | catalogued as COSV63244828; called by muse, mutect2, varscan2
- ADCY2 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs143227108; called by mutect2, varscan2
- ADCY2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57869521; called by muse, mutect2
- ADCY8 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs777025629, COSV53920864; called by mutect2, varscan2
- ADD2 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs781925181, COSV52457882; called by muse, mutect2, varscan2
- ADGRA2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs150153046; called by muse, mutect2, varscan2
- ADGRB2 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1438761095, COSV57070223, COSV57076115; called by muse, mutect2, varscan2
- ADGRB3 | c.3514G>A p.D1172N | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV53247619, COSV53261891; called by muse, mutect2, varscan2
- ADGRF1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs151335777; called by muse, mutect2, varscan2
- ADGRG1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 114/402 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as rs575567117, COSV101113369; called by muse, mutect2, varscan2
- ADGRG2 | c.2321C>A p.P774Q (on ENST00000379869 / NM_001079858.3; = p.P771Q on NM_005756.4) | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV61338032; called by muse, mutect2, varscan2
- ADGRG4 | c.1961C>T p.T654I | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.981); catalogued as COSV54966038; called by muse, mutect2, varscan2
- ADGRG4 | c.5978C>A p.S1993Y | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54966777; called by muse, mutect2, varscan2
- ADGRG4 | c.6821C>T p.S2274L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1272460149, COSV54956046; called by muse, mutect2, varscan2
- ADGRG6 | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs762950556; called by muse, mutect2, varscan2
- ADGRG7 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs778508765; called by mutect2, varscan2
- ADGRL1 | c.4345G>A p.E1449K (on ENST00000340736 / NM_001008701.3; = p.E1444K on NM_014921.5) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs368398999, COSV61565289; called by muse, mutect2, varscan2
- ADGRL3 | c.3057C>A p.F1019L (on ENST00000506720 / NM_001322402.2; = p.F951L on NM_015236.6) | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); catalogued as COSV72231272; called by muse, mutect2, varscan2
- ADGRL3 | c.3335A>C p.Y1112S (on ENST00000506720 / NM_001322402.2; = p.Y1044S on NM_015236.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV72231138; called by muse, mutect2, varscan2
- ADGRL4 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as rs767685899, COSV66060741; called by mutect2, varscan2
- ADGRV1 | c.14224G>A p.E4742K | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs372362723, COSV67984217; called by muse, mutect2, varscan2
- ADH1B | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs768162102, COSV59295799; called by muse, mutect2, varscan2
- ADH4 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.189); catalogued as rs200208857; called by muse, varscan2
- ADH7 | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as rs142925520; called by muse, mutect2, varscan2
- ADPRH | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 48/486 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780404094; called by muse, mutect2
- ADRA1A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 56/281 reads (20%) | catalogued as COSV52359933; called by muse, mutect2, varscan2
- ADRM1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1248219132, COSV53370852; called by muse, mutect2, varscan2
- AF196969.1 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.28); catalogued as rs1335777232, COSV52141508; called by muse, varscan2
- AFAP1L2 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1191746735; called by muse, varscan2
- AFF3 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57839667; called by muse, mutect2, varscan2
- AFG1L | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs778941841, COSV100933937; called by muse, mutect2, varscan2
- AFG3L2 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52314266; called by muse, mutect2
- AFG3L2 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777218796, COSV52313972, COSV52317336; called by muse, varscan2
- AFG3L2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as rs148364117; called by muse, mutect2, varscan2
- AFP | c.685A>C p.N229H | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs777897812; called by muse, varscan2
- AGAP2 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV57726756, COSV99224080; called by muse, mutect2, varscan2
- AGAP6 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 33/694 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as rs1427932690; called by muse, mutect2
- AGBL2 | c.1219C>A p.L407I | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV54093580; called by muse, mutect2
- AGBL4 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs947029939; called by muse, mutect2, varscan2
- AGFG1 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs1488255935; called by muse, mutect2, varscan2
- AGO1 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs1262161642, COSV64595240, COSV64596117; called by muse, mutect2, varscan2
- AGRN | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as rs1438592464, COSV65071832; called by muse, mutect2
- AGTPBP1 | c.2585T>C p.L862S (on ENST00000357081 / NM_001330701.2; = p.L822S on NM_015239.2) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61270335; called by muse, mutect2, varscan2
- AGXT | c.671A>G p.D224G | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as rs1253098618; called by muse, mutect2, varscan2
- AHI1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as rs779678242; called by muse, mutect2, varscan2
- AHNAK | c.8519T>C p.I2840T | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs773254245; called by muse, mutect2, varscan2
- AHNAK | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs201304148; called by muse, mutect2, varscan2
- AHNAK2 | c.16035G>T p.E5345D | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.724); catalogued as COSV100316795; called by muse, mutect2
- AHNAK2 | c.14135C>A p.S4712Y | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100315461; called by muse, mutect2
- AHNAK2 | c.11824G>T p.G3942* | Nonsense Mutation (SNP) | VAF 30/524 reads (6%) | catalogued as COSV60926322; called by muse, mutect2
- AHR | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs908053629; called by muse, mutect2
- AIFM3 | c.1106G>T p.R369M | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV59003608; called by muse, mutect2
- AIMP1 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 49/183 reads (27%) | catalogued as rs373122636; called by muse, mutect2, varscan2
- AIMP1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 60/390 reads (15%) | catalogued as rs755959621, COSV63638898; called by muse, mutect2, varscan2
- AIMP1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs936406926; called by muse, mutect2
- AJUBA | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV52984474; called by muse, mutect2
- AK5 | c.106G>T p.E36* (on ENST00000354567 / NM_174858.3; = p.E10* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as COSV58356127; called by muse, mutect2
- AKAP12 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs371840865; called by mutect2, varscan2
- AKAP13 | c.7822C>T p.R2608C (on ENST00000394518 / NM_007200.5; = p.R2612C on NM_006738.6) | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs750119172, COSV63472181; called by muse, mutect2, varscan2
- AKAP17A | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 39/380 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1487216655, COSV58311966, COSV58312170; called by muse, mutect2, varscan2
- AKAP17A | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV58309067; called by muse, mutect2, varscan2
- AKAP4 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.817); catalogued as rs782377975, COSV62074933; called by muse, varscan2
- AKAP5 | c.419A>C p.N140T | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs937849865; called by muse, varscan2
- AKAP8 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.356); catalogued as rs567290517; called by muse, varscan2
- AKAP9 | c.2853G>T p.E951D | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1490879515; called by muse, mutect2, varscan2
- AKAP9 | c.5641C>T p.R1881* (on ENST00000359028; = p.R1849* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/324 reads (9%) | catalogued as COSV100661970; called by muse, mutect2
- AKR1E2 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs751902623; called by mutect2, varscan2
- AL121899.2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs556533732, COSV101198521; called by muse, mutect2, varscan2
- AL645922.1 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 47/503 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.631); catalogued as COSV54962952; called by muse, mutect2
- ALCAM | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.239); catalogued as COSV60257231; called by muse, varscan2
- ALCAM | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60250891; called by muse, mutect2, varscan2
- ALDH8A1 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 46/502 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.041); catalogued as rs751359207; called by muse, mutect2
- ALG11 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201526759, COSV73000831; called by muse, mutect2, varscan2
- ALG13 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.271); catalogued as COSV52640199; called by muse, mutect2, varscan2
- ALG13 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99322116; called by muse, varscan2
- ALG13 | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as rs1481572636; called by muse, mutect2
- ALG9 | c.1798C>T p.R600W (on ENST00000614444 / NM_001352418.1; = p.R607W on NM_024740.2) | Missense Mutation (SNP) | VAF 75/437 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs781849410; called by muse, mutect2, varscan2
- ALKBH8 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs1278747944; called by muse, mutect2, varscan2
- ALOXE3 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV59074265; called by muse, mutect2
- ALPG | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs780147110, COSV54966220; called by muse, varscan2
- ALS2CL | c.2584G>A p.G862R | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.821); catalogued as rs368356424; called by muse, mutect2, varscan2
- ALX4 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV61325932; called by muse, mutect2, varscan2
- AMBRA1 | c.3599C>T p.A1200V (on ENST00000458649 / NM_001367468.1; = p.A1110V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as rs866037672; called by muse, mutect2
- AMDHD2 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1218676938; called by muse, mutect2
- AMER2 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs559614059; called by muse, mutect2, varscan2
- AMMECR1 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 36/129 reads (28%) | catalogued as COSV99466123; called by muse, mutect2, varscan2
- AMMECR1L | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 57/521 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1411675264, COSV55760064; called by muse, mutect2, varscan2
- AMOT | c.2115G>T p.Q705H (on ENST00000371959 / NM_001113490.1; = p.Q296H on NM_133265.3) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100495004; called by muse, varscan2
- AMOT | c.1723C>T p.R575* (on ENST00000371959 / NM_001113490.1; = p.R166* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 17/247 reads (7%) | catalogued as rs1325679862, COSV100495544, COSV59064016; called by muse, mutect2
- AMY2B | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 35/488 reads (7%) | catalogued as rs770249517, COSV63714026; called by muse, mutect2
- ANAPC7 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs764584620; called by muse, mutect2, varscan2
- ANHX | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1462863125, COSV101376540; called by muse, mutect2, varscan2
- ANK2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1474105619, COSV52152842; called by muse, mutect2
- ANK2 | c.5264C>A p.S1755Y | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52145274; called by muse, mutect2
- ANK2 | c.8062C>T p.R2688* | Nonsense Mutation (SNP) | VAF 62/310 reads (20%) | catalogued as rs765199439, COSV52154516; called by muse, varscan2
- ANK2 | c.9646G>T p.E3216* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100002897; called by muse, mutect2, varscan2
- ANK3 | c.3241C>T p.R1081* (on ENST00000280772 / NM_001320874.2; = p.R215* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 69/247 reads (28%) | catalogued as rs775324952, COSV55059130; called by muse, varscan2
- ANKEF1 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs1568516713, COSV65692061; called by muse, mutect2
- ANKFN1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555939322, COSV59453904; called by muse, mutect2, varscan2
- ANKH | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 101/478 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV52477457; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs1430453747; called by muse, mutect2, varscan2
- ANKIB1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV56059697; called by muse, mutect2, varscan2
- ANKRD12 | c.5710C>T p.R1904* | Nonsense Mutation (SNP) | VAF 31/112 reads (28%) | catalogued as rs891449557, COSV50832535; called by muse, varscan2
- ANKRD18B | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1219934771; called by muse, mutect2, varscan2
- ANKRD26 | c.3439C>T p.R1147* | Nonsense Mutation (SNP) | VAF 51/161 reads (32%) | catalogued as rs151033255, COSV65774138; called by muse, mutect2, varscan2
- ANKRD29 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99409040; called by muse, mutect2, varscan2
- ANKRD30B | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.119); catalogued as rs762129679; called by muse, mutect2, varscan2
- ANKRD30B | c.674T>G p.L225R | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62826100; called by muse, mutect2, varscan2
- ANKRD30B | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 107/342 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV100746833; called by muse, mutect2, varscan2
- ANKRD30B | c.3091G>T p.E1031* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs761505137, COSV100271418; called by muse, mutect2, varscan2
- ANKRD30B | c.3505G>T p.E1169* | Nonsense Mutation (SNP) | VAF 50/136 reads (37%) | catalogued as COSV100271384; called by muse, mutect2, varscan2
- ANKRD31 | c.1690A>G p.M564V | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs1357505064; called by muse, mutect2, varscan2
- ANKRD34B | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs965209696, COSV58614468; called by muse, mutect2
- ANKRD35 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1553738774; called by muse, mutect2, varscan2
- ANKRD36C | c.4207G>T p.D1403Y | Missense Mutation (SNP) | VAF 30/443 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV69433130; called by muse, mutect2
- ANKRD36C | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.55); catalogued as rs1455228770; called by muse, mutect2
- ANKRD50 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs368512857; called by mutect2, varscan2
- ANKRD62 | c.2350C>A p.L784M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58412155; called by muse, varscan2
- ANLN | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs923512260, COSV56074093; called by muse, mutect2, varscan2
- ANO1 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748145836; called by muse, mutect2, varscan2
- ANO4 | c.925C>T p.R309* (on ENST00000392977 / NM_001286615.2; = p.R274* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 37/132 reads (28%) | catalogued as rs866684439, COSV104407411, COSV54586554; called by muse, mutect2, varscan2
- ANO4 | c.1792C>A p.L598I (on ENST00000392977 / NM_001286615.2; = p.L563I on NM_178826.4) | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs267603264, COSV54614934; called by muse, mutect2, varscan2
- ANO4 | c.2857G>A p.E953K (on ENST00000392977 / NM_001286615.2; = p.E918K on NM_178826.4) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1566286837; called by muse, mutect2
- ANO8 | c.350+2C>T p.X117_splice | Splice Site (SNP) | VAF 24/127 reads (19%) | catalogued as COSV50176846; called by muse, mutect2, varscan2
- AOAH | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV51736413, COSV99332448; called by muse, mutect2, varscan2
- AOC1 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374401802, COSV62866867; called by muse, varscan2
- AOC1 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs201157437; called by muse, mutect2, varscan2
- AOPEP | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs960335746; called by muse, mutect2, varscan2
- AOX1 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as rs754596150, COSV65981094; called by muse, mutect2, varscan2
- AOX1 | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.458); catalogued as COSV101021938; called by muse, mutect2, varscan2
- AOX1 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs140180293; called by muse, varscan2
- AP3D1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs769763871; called by muse, mutect2, varscan2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by muse, mutect2, varscan2
- AP4B1 | c.1697T>C p.V566A | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs373733045; called by muse, mutect2, varscan2
- AP4B1 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as CD121083; called by mutect2, varscan2
- AP4E1 | c.3118G>A p.D1040N | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs368578986; called by muse, mutect2, varscan2
- AP5Z1 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196396832, COSV100804200; called by muse, mutect2, varscan2
- APBA2 | c.311G>C p.C104S | Missense Mutation (SNP) | VAF 55/470 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101382611; called by muse, mutect2, varscan2
- APBA2 | c.1521G>T p.E507D | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV67104486; called by muse, varscan2
- APC | c.5582C>A p.S1861Y | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD961780, COSV104379185, COSV57328606; called by muse, varscan2
- APC | c.5591C>A p.S1864Y | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57335012, COSV57362314; called by muse, varscan2
- APC | c.7715C>A p.S2572* | Nonsense Mutation (SNP) | VAF 42/138 reads (30%) | catalogued as COSV57333966; called by muse, varscan2
- APC2 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.076); catalogued as rs748431523; called by muse, mutect2, varscan2
- APCDD1 | c.287G>T p.R96I | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.205); catalogued as COSV62372552; called by muse, mutect2, varscan2
- APLF | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58149210; called by muse, mutect2, varscan2
- APLNR | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs780061917, COSV57241774, COSV57243829; called by muse, mutect2, varscan2
- APLP1 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as rs1321429015, COSV55706158; called by muse, mutect2
- APOB | c.12646C>A p.L4216I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs1426611693; called by muse, mutect2, varscan2
- APOB | c.5375C>T p.S1792F | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV51930166; called by muse, mutect2, varscan2
- APOBEC3A | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs752810094, COSV50779242; called by mutect2, varscan2
- APOBEC3B | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | catalogued as rs1397292493; called by muse, mutect2, varscan2
- APOBEC3G | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 14/108 reads (13%) | catalogued as COSV68470520; called by mutect2, varscan2
- APOH | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as COSV52773675; called by muse, mutect2, varscan2
- AQR | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as rs776265279, COSV50033316; called by muse, mutect2, varscan2
- AR | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65963461; called by muse, mutect2, varscan2
- ARF5 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV99133706; called by muse, mutect2, varscan2
- ARFIP2 | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV54446341; called by muse, mutect2
- ARG2 | c.184+2T>C p.X62_splice | Splice Site (SNP) | VAF 58/150 reads (39%) | catalogued as COSV99937427; called by muse, varscan2
- ARHGAP1 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.394); catalogued as rs374411055; called by muse, mutect2, varscan2
- ARHGAP11A | c.2774C>T p.S925L | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs763115745; called by muse, mutect2, varscan2
- ARHGAP15 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54476321, COSV54477162; called by muse, mutect2, varscan2
- ARHGAP17 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV104390804; called by muse, mutect2, varscan2
- ARHGAP18 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs757913140, COSV63764480; called by muse, mutect2, varscan2
- ARHGAP20 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs762134281, COSV52810526; called by muse, mutect2, varscan2
- ARHGAP21 | c.4271C>T p.P1424L | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs774810878, COSV100256519; called by muse, mutect2, varscan2
- ARHGAP21 | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.601); catalogued as rs1389550410; called by muse, varscan2
- ARHGAP23 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs1245341765; called by muse, mutect2, varscan2
- ARHGAP24 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 54/309 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67837028; called by muse, mutect2, varscan2
- ARHGAP24 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374671512; called by muse, mutect2, varscan2
- ARHGAP28 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.63); catalogued as rs541347505, COSV51638013; called by muse, varscan2
- ARHGAP28 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs200524496; called by muse, varscan2
- ARHGAP28 | c.1939G>A p.A647T (on ENST00000383472 / NM_001366230.1; = p.A488T on NM_001010000.3) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203525791, COSV51632031; called by muse, varscan2
- ARHGAP29 | c.3101G>T p.R1034I | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99557447; called by muse, varscan2
- ARHGAP36 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs1057296329; called by muse, mutect2, varscan2
- ARHGAP4 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1557103127; called by muse, varscan2
- ARHGAP44 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52394460; called by muse, mutect2, varscan2
- ARHGAP5 | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61537726; called by muse, mutect2, varscan2
- ARHGAP9 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs773143456; called by muse, mutect2, varscan2
- ARHGEF1 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs370594565; called by muse, mutect2, varscan2
- ARHGEF10 | c.2775C>T p.I925= (on ENST00000398564; = p.I900= on NM_014629.4) | Splice Region (SNP) | VAF 24/431 reads (6%) | catalogued as rs1045482998; called by muse, mutect2
- ARHGEF10L | c.3500G>A p.R1167H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs763490533, COSV51435224; called by muse, mutect2, varscan2
- ARHGEF11 | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63811413; called by muse, mutect2
- ARHGEF12 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV63106027; called by muse, mutect2
- ARHGEF12 | c.3095G>T p.R1032I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV63104617; called by muse, mutect2, varscan2
- ARHGEF16 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1044711339; called by muse, mutect2
- ARHGEF26 | c.821G>T p.R274I | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100726650; called by muse, mutect2, varscan2
- ARID1B | c.4916C>T p.T1639M | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1215965074, COSV51671801; called by muse, mutect2
- ARID2 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV100535319; called by muse, varscan2
- ARID3C | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs368164274; called by muse, mutect2, varscan2
- ARID4B | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51607416; called by muse, varscan2
- ARID5B | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 105/326 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV54425484, COSV99690532; called by muse, varscan2
- ARIH1 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as rs768710024; called by muse, mutect2, varscan2
- ARL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033216289, COSV55370222; called by muse, mutect2, varscan2
- ARL11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs769095684; called by muse, varscan2
- ARL2BP | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs778187320, COSV54655628; called by muse, mutect2, varscan2
- ARL8A | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as rs769466486; called by muse, mutect2, varscan2
- ARMC2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 24/164 reads (15%) | catalogued as COSV52900365; called by muse, mutect2, varscan2
- ARMC4 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 70/398 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs749814633; called by muse, varscan2
- ARMC9 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | catalogued as rs1330612935; called by muse, mutect2, varscan2
- ARMCX1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs1556027234, COSV65705516; called by muse, mutect2, varscan2
- ARMCX5 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs762914687; called by muse, varscan2
- ARMCX5-GPRASP2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs369432744, COSV100771865, COSV63438046; called by muse, varscan2
- ARMH4 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750555182, COSV50767618; called by muse, varscan2
- ARNTL2 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as rs911421382, COSV53824639, COSV99667957; called by muse, varscan2
- ARNTL2 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs758271274, COSV53824759; called by mutect2, varscan2
- ARRB1 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63575602; called by muse, mutect2, varscan2
- ARRDC4 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs759457620, COSV51420299; called by muse, mutect2, varscan2
- ARSD | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs776244005, COSV54203967; called by muse, mutect2, varscan2
- ARSF | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); catalogued as rs188315940; called by muse, varscan2
- ARSF | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.24); catalogued as rs761840114, COSV100839519; called by muse, varscan2
- ARSH | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV66962573; called by muse, mutect2
- ASB14 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs147845490; called by muse, mutect2, varscan2
- ASB15 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs373123954, COSV51923861; called by muse, mutect2
- ASB4 | c.53A>C p.K18T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1562808164; called by muse, mutect2, varscan2
- ASB7 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 88/359 reads (25%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.95); catalogued as COSV58404093; called by muse, varscan2
- ASCC3 | c.5078C>T p.P1693L | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007770313, COSV64978681; called by muse, mutect2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASF1A | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57649082; called by muse, mutect2, varscan2
- ASH1L | c.5599T>C p.F1867L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100853023; called by muse, mutect2, varscan2
- ASIC5 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 44/172 reads (26%) | catalogued as rs1168515854, COSV73332699; called by muse, mutect2, varscan2
- ASIC5 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs745353708, COSV101611163, COSV73332867; called by muse, mutect2
- ASNSD1 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV53625527; called by muse, mutect2, varscan2
- ASPM | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766198125, COSV54132241; called by muse, mutect2, varscan2
- ASTN1 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758946441, COSV99921788; called by muse, mutect2, varscan2
- ASTN2 | c.3692C>T p.S1231L (on ENST00000313400 / NM_001365069.1; = p.S1180L on NM_014010.5) | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1458214989, COSV55999388; called by muse, mutect2, varscan2
- ASTN2 | c.1714C>A p.L572M (on ENST00000313400 / NM_001365069.1; = p.L521M on NM_014010.5) | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57771522; called by muse, varscan2
- ASXL1 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60127455; called by muse, mutect2
- ASXL1 | c.1569G>T p.K523N | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60110541; called by muse, mutect2, varscan2
- ASXL3 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as rs372250848; called by mutect2, varscan2
- ASXL3 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV52461305; called by muse, varscan2
- ATAD2B | c.1560G>T p.Q520H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1220645773; called by muse, mutect2, varscan2
- ATAD5 | c.1550G>A p.R517K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.325); catalogued as rs1398740167; called by muse, mutect2, varscan2
- ATF7IP | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs775807378, COSV53766672; called by muse, mutect2, varscan2
- ATG2B | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759771840; called by muse, mutect2, varscan2
- ATG9B | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100939892; called by muse, mutect2
- ATMIN | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs760212160, COSV55145516; called by mutect2, varscan2
- ATN1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1555143445, COSV63110929; called by muse, mutect2
- ATP11A | c.2668-8C>T | Splice Region (SNP) | VAF 29/174 reads (17%) | catalogued as rs758661182; called by muse, mutect2, varscan2
- ATP13A2 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 151/506 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as rs759966151; called by muse, mutect2, varscan2
- ATP13A3 | c.3526C>T p.R1176* | Nonsense Mutation (SNP) | VAF 30/284 reads (11%) | catalogued as rs1376912188, COSV55468231; called by muse, mutect2
- ATP13A3 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV55462743; called by muse, mutect2, varscan2
- ATP1B4 | c.505G>A p.V169I (on ENST00000218008 / NM_001142447.3; = p.V165I on NM_012069.5) | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as rs763182565, COSV54313957; called by muse, mutect2
- ATP23 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479183882, COSV55685387; called by muse, mutect2
- ATP2A1 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 131/529 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs748538818; called by muse, mutect2, varscan2
- ATP2A2 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 54/325 reads (17%) | catalogued as rs1365408478; called by muse, mutect2, varscan2
- ATP2B2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as rs945844574, COSV59489385; called by muse, mutect2, varscan2
- ATP2B3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs782416017; called by muse, varscan2
- ATP5F1A | c.946A>G p.K316E | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56362112; called by muse, mutect2
- ATP5F1B | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 35/405 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs747376704, COSV51636439; called by muse, mutect2
- ATP6V0E2 | c.163G>A p.A55T (on ENST00000425642; = p.A104T on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1282823901, COSV101374598; called by muse, mutect2
- ATP6V1B2 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 11/155 reads (7%) | catalogued as COSV52354768; called by muse, mutect2
- ATP6V1FNB | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs1422813927; called by muse, varscan2
- ATP6V1G3 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.458); catalogued as rs763283835, COSV55280620; called by muse, varscan2
- ATP7A | c.3154G>A p.G1052R | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782781031; called by muse, mutect2, varscan2
- ATP7B | c.3583G>A p.A1195T | Missense Mutation (SNP) | VAF 94/522 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs202218969; ClinVar: uncertain significance; called by muse, varscan2
- ATP7B | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs1425712013; called by muse, mutect2
- ATP8A1 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.029); catalogued as COSV52532108; called by muse, mutect2, varscan2
- ATP8B1 | c.1005C>A p.Y335* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as COSV52175435; called by muse, mutect2, varscan2
- ATP8B2 | c.1721G>T p.R574L (on ENST00000672630; = p.R541L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59248153; called by muse, varscan2
- ATP9B | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 63/218 reads (29%) | catalogued as rs778501286, COSV100304243; called by muse, mutect2, varscan2
- ATR | c.3536G>A p.R1179K | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.291); catalogued as COSV100637777, COSV63392023; called by muse, mutect2, varscan2
- ATR | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs771309709; called by muse, mutect2, varscan2
- ATRIP | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57176887; called by muse, mutect2
- ATRNL1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as COSV100745804; called by muse, mutect2, varscan2
- ATRX | c.5939C>A p.S1980Y | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV64871058; called by muse, mutect2, varscan2
- ATRX | c.5449-1G>T p.X1817_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | catalogued as COSV64885967; called by muse, mutect2
- ATRX | c.3790G>A p.D1264N | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs782344877, COSV64883860; called by muse, mutect2
- ATRX | c.3490G>T p.D1164Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs781923763, COSV100971028, COSV64878299; called by muse, mutect2
- ATRX | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs376906761, COSV64874330; called by muse, mutect2
- ATXN7L1 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 29/265 reads (11%) | catalogued as rs1347016105; called by muse, mutect2, varscan2
- AUTS2 | c.1690T>C p.F564L | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100717566; called by muse, mutect2, varscan2
- AVEN | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100145871; called by muse, varscan2
- AVL9 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV59464720; called by muse, varscan2
- AVPR2 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.157); catalogued as rs782790439; called by muse, mutect2
- AXIN1 | c.2539C>A p.L847M | Missense Mutation (SNP) | VAF 64/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51987440; called by muse, mutect2, varscan2
- B2M | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 48/210 reads (23%) | catalogued as COSV62562883; called by muse, mutect2, varscan2
- B3GALT5 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58200685; called by mutect2, varscan2
- B4GALT3 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs757070009, COSV60526902; called by mutect2, varscan2
- BACH1 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104379582; called by muse, mutect2, varscan2
- BAG3 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 148/436 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775645671, COSV64841858, COSV64841948; called by muse, mutect2, varscan2
- BAG6 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 64/341 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs897726591; called by muse, mutect2, varscan2
- BAMBI | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs369743386; called by muse, mutect2, varscan2
- BANK1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100535571, COSV59850236; called by muse, mutect2, varscan2
- BBS12 | c.1072C>A p.L358I | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58562849; called by muse, mutect2, varscan2
- BBS2 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs376883866; called by muse, mutect2, varscan2
- BBS9 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99627041; called by muse, mutect2
- BCAN | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs748416928, COSV100227782; called by muse, mutect2, varscan2
- BCAS1 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV65083800; called by muse, mutect2, varscan2
- BCAS3 | c.2122G>A p.D708N (on ENST00000390652 / NM_001353144.2; = p.D693N on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs201061353, COSV66772681; called by mutect2, varscan2
- BCHE | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.204); catalogued as COSV52255254, COSV52261070; called by muse, mutect2, varscan2
- BCKDHB | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs371518124, CM122022; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2
- BCL11B | c.1415G>A p.R472H (on ENST00000357195 / NM_001282237.2; = p.R401H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231938148, COSV61734054; called by muse, mutect2
- BCL2L13 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV58225517; called by muse, mutect2, varscan2
- BCL6 | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 14/188 reads (7%) | catalogued as rs1202633041; called by muse, mutect2
- BCL6B | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 35/311 reads (11%) | catalogued as COSV99546442, COSV99546768; called by muse, mutect2, varscan2
- BCL9 | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs139858510; called by muse, mutect2, varscan2
- BCOR | c.5111G>A p.S1704N (on ENST00000378444 / NM_001123385.2; = p.S1670N on NM_017745.6) | Missense Mutation (SNP) | VAF 74/389 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs775669177, COSV60704268; called by muse, varscan2
- BCORL1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1057180410; called by muse, mutect2
- BDP1 | c.5032A>G p.T1678A | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs776444238; called by muse, varscan2
- BEND5 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs1180213008, COSV65718601; called by muse, mutect2, varscan2
- BFSP1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs751568608, COSV64899414; called by muse, mutect2
- BHLHE40 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs775412121, COSV99848152; called by muse, mutect2, varscan2
- BHMT2 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs776368961; called by muse, mutect2, varscan2
- BICDL1 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs886824529, COSV99985905; called by muse, mutect2, varscan2
- BIRC6 | c.8825C>T p.A2942V | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as rs1423937664; called by muse, mutect2, varscan2
- BLM | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV61927260; called by muse, mutect2, varscan2
- BLOC1S1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57725112; called by muse, mutect2, varscan2
- BMERB1 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.724); catalogued as rs1473247824; called by muse, varscan2
- BMI1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV64959350; called by muse, mutect2, varscan2
- BMP10 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.634); catalogued as COSV54894768; called by muse, mutect2, varscan2
- BMP15 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs782079720, COSV53139772; called by muse, mutect2, varscan2
- BMP6 | c.1205-1G>T p.X402_splice | Splice Site (SNP) | VAF 17/123 reads (14%) | catalogued as COSV51667077; called by muse, mutect2, varscan2
- BMPER | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.343); catalogued as rs1360042798; called by muse, mutect2
- BMPER | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780830; called by muse, mutect2
- BMS1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 57/175 reads (33%) | catalogued as COSV65733572, COSV65733815; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 54/170 reads (32%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BNC1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 43/513 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1018300663, COSV61756678, COSV61757240; called by muse, mutect2
- BNC2 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 154/453 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV66152919; called by muse, mutect2, varscan2
- BNIP3 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 22/254 reads (9%) | catalogued as COSV100893311; called by muse, mutect2
- BOC | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs551152491, COSV56354728; called by muse, mutect2, varscan2
- BOD1L1 | c.9146C>T p.A3049V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs769512613, COSV50008166; called by mutect2, varscan2
- BOD1L1 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as rs549342680, COSV50009283; called by mutect2, varscan2
- BOK | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1300037802; called by muse, mutect2
- BOP1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as rs916181974; called by muse, mutect2
- BPIFB2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs748992554, COSV50063090; called by muse, mutect2, varscan2
- BPIFB6 | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.42); catalogued as COSV100848511; called by muse, mutect2, varscan2
- BPTF | c.2696A>G p.K899R | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.089); catalogued as rs1354856868; called by muse, mutect2, varscan2
- BRCA2 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs765436962; ClinVar: uncertain significance; called by mutect2, varscan2
- BRCA2 | c.5030G>A p.R1677K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs375304428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs775920438, COSV53462510; called by muse, mutect2, varscan2
- BRD4 | c.3695G>A p.R1232Q | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs1023216999, COSV54583371, COSV99650198; called by muse, mutect2, varscan2
- BRD4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs867596343, COSV54583236; called by muse, mutect2
- BRINP2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs745381993; called by muse, varscan2
- BROX | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as rs755992795; called by mutect2, varscan2
- BRWD3 | c.5092G>A p.G1698R | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.02); catalogued as rs777503508, COSV64745937; called by muse, mutect2, varscan2
- BRWD3 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1389357356; called by muse, mutect2
- BRWD3 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV64743373; called by muse, mutect2, varscan2
- BTAF1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1412442556; called by muse, mutect2
- BTAF1 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.733); catalogued as COSV99795561; called by muse, mutect2, varscan2
- BTBD10 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV99533412; called by muse, mutect2
- BTBD11 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.935); catalogued as rs1347183891; called by muse, mutect2
- BTBD11 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs765978569, COSV55021439; called by muse, mutect2, varscan2
- BTBD18 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as rs1344017505; called by muse, mutect2, varscan2
- BTBD7 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs915971782; called by muse, mutect2
- BTBD8 | c.4394C>A p.S1465Y (on ENST00000636805 / NM_001376131.1; = p.S952Y on NM_015237.4) | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs750974736, COSV64884892, COSV64885282; called by muse, mutect2, varscan2
- BTD | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs554439068; called by muse, varscan2
- BTG4 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992892482, COSV63635512; called by muse, mutect2, varscan2
- BTN3A1 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV50025121; called by muse, mutect2, varscan2
- BTN3A3 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs898961869; called by muse, mutect2, varscan2
- BYSL | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs1204320311; called by muse, mutect2, varscan2
- C10orf67 | c.28C>A p.H10N (on ENST00000323327; = p.H11N on NM_153714.3) | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as rs772176578; called by muse, mutect2, varscan2
- C11orf49 | c.756C>T p.L252= | Splice Region (SNP) | VAF 34/169 reads (20%) | catalogued as rs143884410; called by muse, mutect2, varscan2
- C11orf53 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs376710383; called by muse, mutect2, varscan2
- C11orf58 | c.110G>T p.R37I | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV57178767; called by muse, mutect2, varscan2
- C12orf29 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs1565772208; called by muse, mutect2, varscan2
- C12orf40 | c.1217-1G>T p.X406_splice | Splice Site (SNP) | VAF 12/74 reads (16%) | catalogued as COSV61135191; called by muse, mutect2, varscan2
- C12orf66 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); catalogued as COSV61324790; called by muse, mutect2, varscan2
- C14orf93 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54441944; called by muse, mutect2, varscan2
- C19orf12 | c.338C>T p.T113M (on ENST00000392278 / NM_001031726.3; = p.T102M on NM_031448.6) | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs139585199; called by muse, mutect2, varscan2
- C1QB | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV100152778; called by muse, mutect2
- C1orf100 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs749990466; called by muse, mutect2, varscan2
- C1orf100 | c.422G>T p.R141I | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1558260625, COSV57372712; called by muse, varscan2
- C1orf127 | c.2318G>T p.S773I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65439249; called by muse, mutect2, varscan2
- C1orf141 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV63992691; called by mutect2, varscan2
- C1orf146 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV64859816; called by muse, mutect2, varscan2
- C1orf185 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs925923164, COSV65624933, COSV65625240; called by muse, mutect2, varscan2
- C1orf68 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1313335161; called by muse, mutect2
- C21orf91 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as rs1372188991; called by muse, mutect2, varscan2
- C2CD2L | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs757596227, COSV60884219; called by muse, mutect2, varscan2
- C2orf78 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV68517660; called by muse, mutect2, varscan2
- C3 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55573420; called by muse, mutect2
- C3 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 21/365 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55579741; called by muse, mutect2
- C3 | c.1804G>A p.V602M | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290774907, COSV55579928; called by muse, mutect2
- C3AR1 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777072831; called by muse, mutect2, varscan2
- C4orf47 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs752707291; called by muse, mutect2, varscan2
- C4orf54 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867121324; called by muse, mutect2
- C5 | c.4397C>T p.S1466L | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs965313093, COSV99798707; called by muse, mutect2, varscan2
- C5 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs765073719; called by muse, mutect2, varscan2
- C6orf118 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as rs201051493, COSV57813406; called by muse, mutect2, varscan2
- C6orf118 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1400884378, COSV57814230; called by muse, mutect2, varscan2
- C6orf118 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV57813208; called by muse, varscan2
- C8orf48 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs577021237, COSV52046626; called by muse, mutect2, varscan2
- C8orf48 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as rs543203990, COSV52046472; called by muse, mutect2, varscan2
- C8orf76 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99415086; called by muse, mutect2
- C8orf76 | c.360A>G p.E120= | Splice Region (SNP) | VAF 14/51 reads (27%) | catalogued as rs1563800062; called by muse, mutect2
- C9orf116 | c.223-1G>T p.X75_splice | Splice Site (SNP) | VAF 24/83 reads (29%) | catalogued as COSV65646836; called by muse, mutect2, varscan2
- C9orf152 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.323); catalogued as COSV68762895; called by muse, varscan2
- CA2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 39/356 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745556921; called by muse, mutect2, varscan2
- CA5B | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 23/332 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV59417520; called by muse, mutect2
- CABIN1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146817070; called by muse, mutect2, varscan2
- CABIN1 | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as rs748459908, COSV54079064; called by muse, varscan2
- CABIN1 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 88/507 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1367466542; called by muse, mutect2, varscan2
- CACHD1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 64/224 reads (29%) | catalogued as COSV51551815; called by muse, mutect2, varscan2
- CACHD1 | c.2299C>A p.P767T | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51562787; called by muse, mutect2, varscan2
- CACNA1C | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100224136; called by muse, mutect2, varscan2
- CACNA1C | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59695046; called by muse, mutect2
- CACNA1D | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs35057005; called by muse, mutect2, varscan2
- CACNA1E | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777063356, COSV62384452, COSV62413692; called by muse, mutect2, varscan2
- CACNA1E | c.3945C>A p.F1315L | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV62431308; called by muse, mutect2, varscan2
- CACNA1F | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59904412; called by muse, mutect2, varscan2
- CACNA1G | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1299101556; called by muse, mutect2
- CACNA1H | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs750887213, COSV62007042; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.4762A>G p.T1588A | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.026); catalogued as rs1555517834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.4064G>A p.R1355H | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV60808018; called by muse, mutect2, varscan2
- CACNA1I | c.5087G>A p.R1696H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.919); catalogued as rs747482916; called by muse, mutect2, varscan2
- CACNB2 | c.1027G>T p.E343* (on ENST00000324631 / NM_201596.3; = p.E288* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 49/425 reads (12%) | catalogued as rs1554838959, COSV104389537; called by muse, varscan2
- CACNG5 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs187075595, COSV50055080; called by muse, mutect2, varscan2
- CAD | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 27/256 reads (11%) | catalogued as COSV99254548; called by muse, mutect2, varscan2
- CADM2 | c.866C>T p.T289M (on ENST00000407528 / NM_001167674.2; = p.T291M on NM_153184.4) | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67369439; called by muse, varscan2
- CADM3 | c.532C>T p.R178C (on ENST00000368125 / NM_001127173.3; = p.R212C on NM_021189.5) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV63684367, COSV63687799; called by muse, mutect2, varscan2
- CADPS | c.3256G>T p.E1086* | Nonsense Mutation (SNP) | VAF 60/220 reads (27%) | catalogued as COSV51891569; called by muse, mutect2, varscan2
- CADPS | c.3026A>G p.K1009R | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV51890666; called by muse, mutect2, varscan2
- CADPS | c.1913T>G p.L638R | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV51873616, COSV51879339; called by muse, mutect2, varscan2
- CADPS2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373213538; called by muse, mutect2, varscan2
- CALCA | c.242G>T p.R81I | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.925); catalogued as COSV59027808; called by muse, mutect2, varscan2
- CALCB | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1267299186; called by muse, mutect2
- CALCRL | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.552); catalogued as rs1396849967; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1486659949; called by mutect2, varscan2
- CAMK2A | c.1379G>A p.G460D (on ENST00000348628 / NM_171825.2; = p.G471D on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.61); catalogued as rs1167006357; called by muse, mutect2, varscan2
- CAMK4 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs376502428; called by muse, varscan2
- CAMP | c.401G>T p.R134I (on ENST00000296435; = p.R131I on NM_004345.5) | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs1428353784, COSV56481848, COSV99601296; called by muse, mutect2, varscan2
- CAMSAP2 | c.1033C>T p.R345C (on ENST00000236925 / NM_001297707.2; = p.R334C on NM_203459.3) | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1478607160, COSV52667964; called by muse, mutect2, varscan2
- CAMSAP2 | c.2021C>A p.P674H (on ENST00000236925 / NM_001297707.2; = p.P663H on NM_203459.3) | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99373715; called by muse, mutect2, varscan2
- CAMTA1 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.041); catalogued as rs555813461, COSV57900995; called by mutect2, varscan2
- CAND1 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73389521; called by muse, varscan2
- CANT1 | c.494T>A p.M165K | Missense Mutation (SNP) | VAF 40/650 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM110020, COSV100185130; called by muse, mutect2
- CAPN1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1229821379; called by muse, mutect2, varscan2
- CAPN12 | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99400668; called by muse, mutect2
- CAPN2 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 44/190 reads (23%) | catalogued as rs754663998; called by muse, mutect2, varscan2
- CAPS2 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV60823832; called by muse, mutect2, varscan2
- CAPS2 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as COSV100158417; called by muse, mutect2, varscan2
- CARMIL2 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs1437114526; called by muse, mutect2, varscan2
- CARMIL3 | c.1800-1G>A p.X600_splice | Splice Site (SNP) | VAF 48/155 reads (31%) | catalogued as rs1348779608; called by muse, varscan2
- CASC3 | c.1652-1G>A p.X551_splice | Splice Site (SNP) | VAF 17/104 reads (16%) | catalogued as COSV52867756; called by muse, mutect2, varscan2
- CASK | c.2441C>T p.A814V (on ENST00000378163 / NM_001367721.1; = p.A809V on NM_003688.3) | Missense Mutation (SNP) | VAF 21/410 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100587788; called by muse, mutect2
- CASP1 | c.1104A>C p.E368D (on ENST00000436863 / NM_033292.4; = p.E347D on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV52828722; called by muse, mutect2, varscan2
- CASP5 | c.1195A>G p.I399V | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as rs757545547; called by muse, mutect2, varscan2
- CASP8AP2 | c.4982G>A p.S1661N | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1339262579; called by muse, mutect2, varscan2
- CASQ2 | c.957G>T p.E319D | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54767598; called by muse, mutect2, varscan2
- CASS4 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1236494477, COSV64385645; called by muse, mutect2, varscan2
- CASS4 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs773870765; called by mutect2, varscan2
- CASZ1 | c.4000G>A p.D1334N | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1489173195; called by muse, mutect2, varscan2
- CATSPERE | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1044413217; called by muse, mutect2, varscan2
- CATSPERG | c.2487G>T p.K829N | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as COSV53053656; called by muse, mutect2
- CAVIN4 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1469578901; called by muse, mutect2, varscan2
- CBFB | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs753519175, COSV52001926; called by muse, varscan2
- CBL | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 120/373 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755244263, COSV50633583; called by muse, mutect2, varscan2
- CBR1 | c.342T>G p.N114K | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150365005; called by muse, mutect2, varscan2
- CBX6 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); catalogued as COSV99328202; called by muse, mutect2, varscan2
- CC2D2A | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs953243101; called by muse, mutect2
- CC2D2A | c.3763C>T p.R1255* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as rs1271825377, COSV67502192; called by muse, mutect2
- CCAR1 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV56270287, COSV56271988; called by muse, mutect2, varscan2
- CCBE1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 93/558 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as rs147402390; called by muse, mutect2, varscan2
- CCDC102B | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60155040; called by muse, varscan2
- CCDC102B | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as COSV60151314; called by muse, varscan2
- CCDC105 | c.1004C>A p.S335* | Nonsense Mutation (SNP) | VAF 32/161 reads (20%) | catalogued as COSV99479928; called by muse, mutect2, varscan2
- CCDC106 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs756436123; called by muse, mutect2, varscan2
- CCDC106 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as rs1409793014; called by muse, mutect2, varscan2
- CCDC113 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 60/129 reads (47%) | catalogued as rs753262070, COSV54685317; called by muse, mutect2, varscan2
- CCDC122 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs956970006, COSV55708749; called by mutect2, varscan2
- CCDC136 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs564211780, COSV52801795; called by muse, mutect2, varscan2
- CCDC136 | c.3226G>T p.E1076* | Nonsense Mutation (SNP) | VAF 63/386 reads (16%) | catalogued as COSV52804368; called by muse, mutect2, varscan2
- CCDC138 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1461072950; called by muse, mutect2
- CCDC14 | c.1172G>T p.R391I (on ENST00000488653; = p.R343I on NM_022757.5) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100113264, COSV59948136; called by muse, mutect2
- CCDC146 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs752173458, COSV99592189; called by muse, varscan2
- CCDC146 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as rs758101331, COSV53543643, COSV53551611; called by muse, mutect2
- CCDC15 | c.2389G>T p.E797* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV61080939, COSV61083406; called by muse, mutect2, varscan2
- CCDC150 | c.2879T>C p.M960T | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as COSV55873305; called by muse, mutect2, varscan2
- CCDC157 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773932430; called by muse, mutect2, varscan2
- CCDC168 | c.20231C>A p.S6744Y | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.215); catalogued as rs376038536, COSV59425396; called by muse, mutect2, varscan2
- CCDC168 | c.9973C>T p.P3325S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV59422206; called by muse, mutect2
- CCDC168 | c.3104C>T p.T1035M | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs189997066, COSV70554817; called by muse, mutect2, varscan2
- CCDC168 | c.2266G>T p.D756Y | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1345645561; called by muse, mutect2, varscan2
- CCDC30 | c.528C>A p.S176R (on ENST00000340612; = p.S133R on NM_001080850.3) | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs769862128, COSV59604205; called by mutect2, varscan2
- CCDC32 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100786032; called by muse, mutect2, varscan2
- CCDC39 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.717); catalogued as rs1192483792; called by muse, mutect2, varscan2
- CCDC62 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs750658685; called by mutect2, varscan2
- CCDC62 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV99457043; called by muse, mutect2, varscan2
- CCDC71 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs1270568587; called by muse, mutect2, varscan2
- CCDC73 | c.2532G>T p.E844D | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV58794889; called by muse, varscan2
- CCDC88B | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs1027435237, COSV57265979; called by muse, mutect2
- CCDC88C | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as rs368499200; called by muse, mutect2, varscan2
- CCDC93 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs1369322125; called by muse, varscan2
- CCN5 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs200780244, COSV51937454; called by muse, varscan2
- CCNA2 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1041908442; called by muse, mutect2, varscan2
- CCNE1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs1225502237, COSV52904173; called by muse, mutect2, varscan2
- CCNH | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1253903016; called by muse, mutect2, varscan2
- CCNK | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV66274584; called by muse, mutect2, varscan2
- CCNT2 | c.1589C>A p.S530Y | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV51471095; called by muse, mutect2, varscan2
- CCPG1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 39/211 reads (18%) | catalogued as COSV51241608; called by muse, mutect2, varscan2
- CCR5 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs200419576, COSV52751280; called by mutect2, varscan2
- CCSAP | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 99/323 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); catalogued as rs1386458569, COSV52910287; called by muse, mutect2, varscan2
- CCT6A | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1274461513; called by muse, mutect2
- CCT8L2 | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63463669; called by muse, mutect2, varscan2
- CD101 | c.1095C>A p.F365L | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as COSV56717749; called by muse, mutect2, varscan2
- CD163 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 29/473 reads (6%) | catalogued as COSV100775789, COSV100775979; called by muse, mutect2
- CD163L1 | c.3839C>T p.A1280V | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145909473; called by mutect2, varscan2
- CD163L1 | c.3242T>C p.V1081A | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.047); catalogued as rs528528931; called by muse, mutect2, varscan2
- CD1D | c.608-1G>A p.X203_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV63808590; called by muse, mutect2, varscan2
- CD200R1 | c.236G>A p.R79K (on ENST00000471858 / NM_170780.3; = p.R102K on NM_138806.4) | Missense Mutation (SNP) | VAF 63/363 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs1022941795; called by muse, mutect2, varscan2
- CD200R1L | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1245378162, COSV68003867; called by muse, mutect2
- CD209 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 141/552 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV52659939; called by muse, mutect2, varscan2
- CD22 | c.1756A>G p.T586A | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.101); catalogued as rs1387549583; called by muse, mutect2
- CD248 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV60937228; called by muse, mutect2, varscan2
- CD276 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.65); catalogued as rs776686900; called by muse, mutect2, varscan2
- CD36 | c.290T>G p.F97C | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99987290; called by muse, mutect2
- CD37 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745579948; called by muse, mutect2, varscan2
- CD3G | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV52674686; called by muse, mutect2, varscan2
- CD5L | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as rs773798853, COSV63821903, COSV63823426; called by muse, mutect2
- CD6 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | catalogued as COSV57838090; called by muse, mutect2
- CD68 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs1407116139; called by muse, mutect2
- CD79B | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 96/521 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147194821; ClinVar: not provided; called by muse, mutect2, varscan2
- CD82 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as rs766230830, COSV99907403; called by muse, mutect2, varscan2
- CD8B | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs751687141, COSV100514501; called by muse, mutect2, varscan2
- CDC16 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1402148510; called by muse, mutect2, varscan2
- CDC16 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754954340, COSV52958780; called by muse, mutect2, varscan2
- CDC23 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs571885466, COSV67509360; called by muse, mutect2, varscan2
- CDC42BPB | c.5012C>T p.S1671L | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867664425; called by muse, mutect2, varscan2
- CDC7 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); catalogued as rs377519100; called by mutect2, varscan2
- CDCA2 | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57948314; called by muse, mutect2, varscan2
- CDCA7L | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748848014; called by mutect2, varscan2
- CDCA7L | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62261666; called by muse, mutect2, varscan2
- CDH1 | c.812T>A p.V271D | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55729459; called by muse, mutect2, varscan2
- CDH10 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs970306300, COSV100053692; called by muse, mutect2, varscan2
- CDH10 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.348); catalogued as COSV52594907; called by muse, mutect2, varscan2
- CDH10 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049911; called by muse, varscan2
- CDH11 | c.2368G>T p.D790Y | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99217881, COSV99218614; called by muse, mutect2, varscan2
- CDH11 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs781127265, COSV51756103, COSV51770009, COSV99216980; called by mutect2, varscan2
- CDH11 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51763822, COSV99219381; called by muse, mutect2
- CDH12 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV66401295; called by muse, varscan2
- CDH12 | c.1954G>T p.D652Y | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756597334, COSV66399380, COSV66400984, COSV66427006; called by muse, mutect2, varscan2
- CDH13 | c.254G>T p.R85I | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs753900035; called by muse, mutect2, varscan2
- CDH13 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.042); catalogued as rs369911404; called by muse, mutect2, varscan2
- CDH19 | c.1876C>A p.L626I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.681); catalogued as rs1413928670, COSV100051227, COSV50959575; called by muse, varscan2
- CDH2 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.57); catalogued as rs1284016891; called by muse, mutect2, varscan2
- CDH23 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 110/375 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374014052; called by muse, mutect2, varscan2
- CDH26 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54842958; called by muse, mutect2
- CDH4 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs759379228, COSV64645806; called by muse, mutect2
- CDH5 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 68/714 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.083); catalogued as rs774722881; called by muse, mutect2
- CDH6 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1184913833; called by muse, mutect2, varscan2
- CDH6 | c.1316C>A p.S439* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV54069300; called by muse, varscan2
- CDH7 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs774688539, COSV59887931; called by muse, mutect2, varscan2
- CDH8 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54867989; called by muse, mutect2
- CDH9 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227025606, COSV50250823, COSV50509224; called by muse, mutect2
- CDK12 | c.1696C>A p.L566M | Missense Mutation (SNP) | VAF 34/455 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.459); catalogued as COSV71001329, COSV99067787; called by muse, mutect2
- CDK13 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1554335512, COSV51703082, COSV99476032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK4 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56983874; called by muse, mutect2
- CDKL5 | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 51/466 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101183843; called by muse, varscan2
- CDRT1 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs200565380; called by muse, mutect2, varscan2
- CDRT1 | c.532T>C p.C178R | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV99887476; called by muse, mutect2
- CEBPA | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as CD1210607, COSV100204617; called by muse, mutect2, varscan2
- CEBPG | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs1436371796; called by muse, varscan2
- CELSR2 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753959693, COSV99603751; called by muse, mutect2, varscan2
- CELSR2 | c.4327G>A p.V1443M | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs976219081, COSV54767935; called by muse, mutect2, varscan2
- CENPE | c.5647G>T p.E1883* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs561450875; called by muse, mutect2, varscan2
- CENPE | c.4037C>A p.S1346Y | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.459); catalogued as COSV99476866; called by muse, mutect2, varscan2
- CENPF | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); catalogued as COSV65273776; called by muse, mutect2
- CENPF | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs189714127; called by muse, mutect2, varscan2
- CENPJ | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs780968763; called by muse, mutect2, varscan2
- CENPP | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs527454904; called by muse, mutect2, varscan2
- CENPU | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 125/393 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs993674770, COSV55657443; called by muse, mutect2, varscan2
- CENPW | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV64177259; called by muse, mutect2, varscan2
- CEP112 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs762500713; called by muse, mutect2, varscan2
- CEP162 | c.3859C>A p.L1287I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs370171466; called by mutect2, varscan2
- CEP164 | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs767918200; called by muse, mutect2, varscan2
- CEP170 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 35/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100318124; called by muse, mutect2
- CEP192 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1456546964; called by muse, mutect2, varscan2
- CEP192 | c.7400C>A p.S2467Y | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1169473037, COSV58062657; called by muse, mutect2, varscan2
- CEP250 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201227843; called by muse, mutect2, varscan2
- CEP290 | c.6634G>T p.E2212* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as COSV58350782; called by muse, mutect2, varscan2
- CEP290 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 72/275 reads (26%) | catalogued as COSV58349378; called by muse, varscan2
- CEP295 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as rs1433845720; called by muse, mutect2, varscan2
- CEP295 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | catalogued as rs371321662; called by muse, varscan2
- CEP350 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1275522303, COSV62485769, COSV62486106; called by muse, mutect2, varscan2
- CEP350 | c.373C>A p.R125S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62485837; called by muse, mutect2, varscan2
- CEP44 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs769157129, COSV56658367; called by muse, mutect2, varscan2
- CEP55 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1024816244, COSV101016863; called by muse, mutect2, varscan2
- CEP57L1 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.718); catalogued as COSV61244069; called by muse, mutect2, varscan2
- CEP85 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV53332400; called by muse, mutect2, varscan2
- CEP97 | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV100512051, COSV59123918; called by muse, mutect2, varscan2
- CERKL | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100183475, COSV59204839; called by muse, mutect2, varscan2
- CES4A | c.1683C>A p.F561L (on ENST00000648724 / NM_001364782.1; = p.F463L on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100110068; called by muse, varscan2
- CFAP100 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100729374; called by muse, mutect2, varscan2
- CFAP100 | c.957G>A p.E319= | Splice Region (SNP) | VAF 24/240 reads (10%) | catalogued as COSV100729210; called by muse, mutect2
- CFAP206 | c.1091G>T p.R364I | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV51536114; called by muse, mutect2
- CFAP20DC | c.2228C>A p.S743Y (on ENST00000482387 / NM_001351530.2; = p.S492Y on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99919369; called by muse, mutect2, varscan2
- CFAP251 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776727712, COSV56608786; called by muse, varscan2
- CFAP299 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866257430, COSV63880963; called by muse, varscan2
- CFAP46 | c.6451C>A p.L2151I | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54148846; called by muse, mutect2, varscan2
- CFAP54 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1268035546; called by muse, mutect2
- CFAP54 | c.4553G>A p.R1518Q | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.27); catalogued as rs376215734; called by mutect2, varscan2
- CFAP54 | c.6419G>A p.G2140E | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61573137; called by mutect2, varscan2
- CFAP58 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs200132388, COSV57212082, COSV57213757; called by muse, mutect2, varscan2
- CFAP58 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs775995835, COSV100459016; called by mutect2, varscan2
- CFAP61 | c.3412G>T p.D1138Y | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55624639, COSV55646990; called by muse, varscan2
- CFAP92 | c.1041G>T p.E347D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV99414918; called by muse, mutect2, varscan2
- CFAP92 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs200283660; called by muse, mutect2, varscan2
- CFHR4 | c.380C>A p.S127Y (on ENST00000367416 / NM_001201551.2; = p.S128Y on NM_001201550.3) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.795); catalogued as COSV52226258, COSV52237196; called by muse, mutect2, varscan2
- CFHR5 | c.1443C>A p.F481L | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV56823683; called by muse, mutect2
- CFP | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 32/367 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1249586763, COSV104371356; called by muse, mutect2
- CGN | c.2824C>T p.R942* | Nonsense Mutation (SNP) | VAF 28/243 reads (12%) | catalogued as rs1417762574; called by muse, varscan2
- CHAF1A | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748820542, COSV56672765; called by muse, mutect2, varscan2
- CHAF1B | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1382609529, COSV58439649; called by muse, mutect2
- CHAT | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 56/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764077878, COSV60320328; called by muse, varscan2
- CHD1 | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV104370015; called by muse, mutect2, varscan2
- CHD1 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1469219298; called by muse, mutect2
12,783 further variants in this file (8,745 protein-altering or splice-affecting, 2,466 silent, 1,572 other) are not listed here.
